Somatic mutation profile of tumor specimen ASCProject_0289_T2_WES (aliquot ASCProject_0289_T2_WES_1) from CMI case ASCProject_0289, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.8 years (22,949 days).
Specimen ASCProject_0289_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest Wall; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e74af2d3-aefb-4518-a534-be8e19b011f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0289_SALIVA (Saliva), aliquot ASCProject_0289_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e3de804-7787-4821-a1f6-78e8c71762be

The open-access MAF lists 74 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Intron 18, Silent 9, RNA 4, 5'Flank 2, 3'UTR 2, Nonsense Mutation 2, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs727503093, COSV54244375; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ABCC9 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886039121, COSV53976492; ClinVar: uncertain significance; called by mutect2, varscan2
- BCL6 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs1202633041; called by mutect2, varscan2
- BHMT2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs145234986; called by mutect2, varscan2
- CHST12 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99324742; called by mutect2, varscan2
- EPB42 | c.275C>A p.A92E (on ENST00000441366 / NM_001114134.2; = p.A122E on NM_000119.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55752520; called by muse, mutect2, varscan2
- FLT4 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774554521, COSV56112322, COSV99987558; called by muse, mutect2, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, varscan2
- NLRP3 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs767011471, COSV60220242, COSV60225995; called by mutect2, varscan2
- NPIPB15 | c.132C>G p.H44Q | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs763190214, COSV70437206; called by muse, mutect2
- OTOG | c.3105G>C p.M1035I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61129222; called by muse, mutect2, varscan2
- TRRAP | c.8324C>T p.A2775V (on ENST00000359863 / NM_001244580.1; = p.A2757V on NM_003496.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as rs764087337, COSV62849990; called by mutect2, varscan2
- TTN | c.6490G>A p.A2164T (on ENST00000591111; = p.A2118T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | PolyPhen probably damaging (0.966); catalogued as rs56285559, CM1510358; ClinVar: likely benign; called by mutect2, varscan2
- USP51 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.401); catalogued as COSV101540636; called by mutect2, varscan2
- ZBTB48 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1417978097; called by muse, mutect2, varscan2
- AAR2 | c.1093A>T p.R365* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | called by muse, varscan2
- CIZ1 | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); called by mutect2, varscan2
- COL2A1 | c.2687C>T p.T896I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DSG2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by mutect2, varscan2
- ESCO2 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GPR68 | c.518_519del p.F173* | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- GYG1 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); called by mutect2, varscan2
- IGFBP7 | c.791_792del p.T264Sfs*3 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.3022G>A p.D1008N (on ENST00000286628 / NM_001161352.2; = p.D950N on NM_002247.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MIA3 | c.2003G>A p.S668N | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- NFAT5 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- NTRK2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, varscan2
- PLOD1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by mutect2, varscan2
- RNF214 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by mutect2, varscan2
- SLC26A7 | c.1269G>C p.Q423H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC4A4 | c.2320G>A p.G774R (on ENST00000264485 / NM_001098484.3; = p.G730R on NM_003759.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- SRGAP1 | c.1754G>C p.R585P | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL1 | c.1468G>C p.A490P (on ENST00000543823; = p.A478P on NM_032872.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- TTC3 | c.5024+1G>A p.X1675_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- TYW3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by mutect2, varscan2
- USP15 | c.2117G>A p.G706E (on ENST00000280377 / NM_001351159.2; = p.G677E on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0.326); called by muse, varscan2
- ZSCAN4 | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTN4 | c.1077G>A p.T359= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs764804381; called by mutect2, varscan2
- FLNA | c.5586C>T p.Y1862= (on ENST00000369850 / NM_001110556.2; = p.Y1854= on NM_001456.3) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs782051964, COSV61044524; called by mutect2, varscan2
- MAK | c.1647C>G p.S549= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100504783; called by mutect2, varscan2
- PCDHA13 | c.2178G>A p.P726= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1474628802, COSV56501101; called by muse, mutect2, varscan2
- PRPS1L1 | c.165C>T p.I55= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs749613723, COSV72649918; called by muse, mutect2, varscan2
- RASGEF1B | c.615C>T p.D205= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- RSRC2 | c.1023C>A p.G341= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- SDK2 | c.810C>A p.T270= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- TRMT2A | c.885C>T p.F295= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2
- AK2 | c.*374A>C | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- ATF1 | c.94-7606T>C | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs1285432255; called by mutect2, varscan2
- DOCK6 | c.45-54C>G | Intron (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- DPPA3P2 | n.639del | RNA (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- ENPP3 | c.78+1075T>G | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs1403225537; called by muse, mutect2
- GEMIN6 | c.128+229T>C | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as rs1381764504; called by muse, mutect2
- GSDMD | c.410+184G>C | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as rs940438988; called by mutect2, varscan2
- KRT8P11 | n.113C>A | RNA (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- LRRC69 | c.184-6223T>C | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as rs1388079873; called by mutect2, varscan2
- MILR1 | chr17:64468342 T>G | 3'Flank (SNP) | VAF 6/36 reads (17%) | catalogued as rs1359421492; called by mutect2, varscan2
- NDUFAF1 | c.759+663dup | Intron (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- NSMF | c.1047+44A>T | Intron (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- OR7E5P | n.187del | RNA (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- PDLIM5 | c.96+1082A>G | Intron (SNP) | VAF 14/150 reads (9%) | catalogued as rs1229870060; called by muse, varscan2
- PDLIM5 | c.96+1083A>G | Intron (SNP) | VAF 13/150 reads (9%) | catalogued as rs1287450621, COSV104400860; called by muse, varscan2
- PKNOX1 | c.*2038T>C | 3'UTR (SNP) | VAF 12/70 reads (17%) | catalogued as rs1335844212; called by muse, mutect2, varscan2
- RAB26 | c.307-418T>A | Intron (SNP) | VAF 10/68 reads (15%) | catalogued as rs1407315531; called by muse, varscan2
- RARS1 | c.46-349A>G | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as rs1268486355; called by mutect2, varscan2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 16/113 reads (14%) | catalogued as rs1426585233; called by muse, varscan2
- RN7SL484P | chr15:99790369 T>C | 5'Flank (SNP) | VAF 6/34 reads (18%) | catalogued as rs1400727918; called by mutect2, varscan2
- SGF29 | c.225-425T>C | Intron (SNP) | VAF 6/33 reads (18%) | catalogued as rs1302420508; called by mutect2, varscan2
- SSH1 | c.111-13624A>G | Intron (SNP) | VAF 18/136 reads (13%) | catalogued as rs1382553106, COSV58468320; called by muse, varscan2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, varscan2
- UACA | c.78+9258A>G | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs1179514522; called by muse, varscan2
- XIST | n.11190C>G | RNA (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- ZBTB8A | chr1:32536198 C>G | 5'Flank (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- ZNF93 | c.227-1162T>A | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs994893137; called by mutect2, varscan2
